Somatic mutation profile of tumor specimen TCGA-XR-A8TF-01A (aliquot TCGA-XR-A8TF-01A-11D-A35Z-10) from TCGA case TCGA-XR-A8TF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 74.3 years (27,145 days).
Specimen TCGA-XR-A8TF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63bbc514-8328-4137-8b7a-d3415894b40e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XR-A8TF-10A (Blood Derived Normal), aliquot TCGA-XR-A8TF-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ace9f32-2853-42b0-bdbe-74c790afb3b0

The open-access MAF lists 158 somatic variants for this specimen: 117 protein-altering or splice-affecting, 36 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 36, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 5, RNA 2, In Frame Del 1, 3'UTR 1, 5'Flank 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 47/137 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4282T>A p.L1428M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228664; called by muse, mutect2, varscan2
- ANKRD13A | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV99923871; called by muse, mutect2, varscan2
- ANKRD30A | c.3286A>T p.N1096Y (on ENST00000611781; = p.N1040Y on NM_052997.2) | Missense Mutation (SNP) | VAF 190/389 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100653146; called by muse, mutect2, varscan2
- ANKS6 | c.1568-2A>T p.X523_splice | Splice Site (SNP) | VAF 42/109 reads (39%) | catalogued as COSV100782245; called by muse, mutect2, varscan2
- APPL1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 157/251 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99897511; called by muse, mutect2, varscan2
- ARAP3 | c.4179G>T p.E1393D | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99499460; called by muse, mutect2
- ARHGAP20 | c.3523G>C p.G1175R | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99503481; called by muse, mutect2, varscan2
- ASMTL | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101187721; called by muse, mutect2
- ATG9B | c.656T>A p.L219Q | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100726154; called by muse, mutect2, varscan2
- ATG9B | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs374984486, COSV52502232, COSV99874063; called by muse, mutect2, varscan2
- ATOH8 | c.614A>G p.D205G | Missense Mutation (SNP) | VAF 85/149 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100092506; called by muse, mutect2, varscan2
- ATRN | c.3961C>T p.Q1321* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as COSV99496841; called by muse, mutect2, varscan2
- AXIN1 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99249485; called by muse, mutect2, varscan2
- CANX | c.1007C>G p.A336G | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV99910312; called by muse, mutect2, varscan2
- CCDC170 | c.1874T>C p.M625T | Missense Mutation (SNP) | VAF 188/215 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99498263; called by muse, mutect2, varscan2
- CCER1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs866986813, COSV62648031; called by muse, mutect2, varscan2
- CCNA1 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV99714420; called by muse, varscan2
- CERKL | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1378155485, COSV100183377; called by muse, mutect2, varscan2
- CHD7 | c.6616G>T p.E2206* | Nonsense Mutation (SNP) | VAF 58/200 reads (29%) | catalogued as COSV101418089; called by muse, mutect2, varscan2
- CMTM7 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); catalogued as rs1354945329, COSV100569881; called by muse, mutect2, varscan2
- CNOT9 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99813649; called by muse, mutect2, varscan2
- COL4A4 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 518/878 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100306462; called by muse, mutect2, varscan2
- COL5A1 | c.2168A>T p.Q723L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100879704; called by muse, mutect2, varscan2
- CPA6 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV52745155, COSV99913012; called by muse, mutect2, varscan2
- CRYGN | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV100484713, COSV61564488; called by muse, mutect2
- DEPDC5 | c.3170A>C p.N1057T (on ENST00000400246; = p.N1126T on NM_014662.5) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV99834787; called by muse, mutect2
- DHX35 | c.1485G>C p.M495I | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.655); catalogued as COSV99326608; called by muse, mutect2, varscan2
- DNAH9 | c.11927A>T p.E3976V | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99304914; called by muse, mutect2, varscan2
- EGFR | c.3484A>T p.S1162C | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as COSV99288624; called by muse, mutect2
- ELP3 | c.120-2A>T p.X40_splice | Splice Site (SNP) | VAF 44/71 reads (62%) | catalogued as COSV99833865; called by muse, mutect2
- ESPL1 | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99229051; called by muse, mutect2, varscan2
- ESRRG | c.399C>G p.D133E | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100752554; called by muse, mutect2, varscan2
- FBN1 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100354261; called by muse, mutect2
- FMN2 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100143999; called by muse, mutect2, varscan2
- FXR1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99976256; called by muse, mutect2, varscan2
- GLRA1 | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199481; called by muse, mutect2, varscan2
- GPR37 | c.595A>T p.K199* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as COSV100390661; called by muse, mutect2, varscan2
- GRIK5 | c.2402T>A p.M801K | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV99490269; called by muse, mutect2, varscan2
- HAND1 | c.263T>A p.L88H | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.221); catalogued as COSV99163960; called by muse, mutect2, varscan2
- IL10 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 62/132 reads (47%) | catalogued as rs1274280163, COSV65594970; called by muse, mutect2, varscan2
- IL21R | c.331A>T p.S111C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100559923; called by muse, mutect2, varscan2
- KCNA6 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768465; called by muse, mutect2, varscan2
- KCNH4 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV99236944, COSV99237799; called by muse, mutect2, varscan2
- KCNN3 | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV99677818; called by muse, mutect2, varscan2
- LANCL3 | c.274T>A p.Y92N | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV101065538; called by muse, mutect2, varscan2
- LARP6 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs146941351, COSV100150632; called by muse, mutect2, varscan2
- LONP2 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV99588738; called by muse, mutect2, varscan2
- LPIN1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV99877278; called by muse, mutect2, varscan2
- LRBA | c.3619C>G p.Q1207E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100841164, COSV63950353; called by muse, mutect2, varscan2
- LZTS1 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV99742805; called by muse, mutect2, varscan2
- MAFA | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV100339121; called by muse, mutect2, varscan2
- MIA2 | c.2360T>G p.I787S | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99697445; called by muse, mutect2, varscan2
- MMP8 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99368304; called by muse, mutect2, varscan2
- MSRB1 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99238098; called by muse, mutect2, varscan2
- MTERF1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 55/193 reads (28%) | catalogued as COSV100699555; called by muse, mutect2, varscan2
- MUC16 | c.21014T>G p.L7005W | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV101198941; called by muse, mutect2, varscan2
- MVK | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99949907; called by muse, varscan2
- NDUFA2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs370015250; called by muse, mutect2, varscan2
- NELFB | c.729G>T p.R243S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100546839; called by muse, mutect2, varscan2
- NLRC5 | c.2099A>G p.D700G | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV99346774; called by muse, mutect2, varscan2
- NRBP2 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs372417243; called by muse, mutect2, varscan2
- NUP37 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV99195839; called by muse, mutect2, varscan2
- OR11L1 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100869399; called by muse, mutect2
- OR4A47 | c.418_419del p.V140Cfs*19 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs765807982; called by pindel, varscan2
- OSBPL5 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751956572, COSV99720185; called by muse, mutect2, varscan2
- PCDHA2 | c.1801T>A p.S601T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100973706; called by muse, mutect2, varscan2
- PLA2G15 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV99547146; called by muse, mutect2, varscan2
- PLS1 | c.216T>G p.S72R | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100538017; called by muse, mutect2
- POTEF | c.2319C>A p.H773Q | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100664717, COSV62542338; called by muse, varscan2
- PRDM14 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99399987; called by muse, mutect2, varscan2
- PRKCG | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99668714; called by muse, mutect2, varscan2
- PRR18 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.48); catalogued as rs887694080, COSV100491411; called by muse, mutect2, varscan2
- PTK2 | c.2810A>C p.E937A | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV100569815; called by muse, mutect2, varscan2
- PTPN11 | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 201/472 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100692348; called by muse, mutect2, varscan2
- REEP2 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1320724041, COSV99649541; called by muse, mutect2, varscan2
- RTKN2 | c.1600A>T p.S534C | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV100189280; called by muse, mutect2, varscan2
- SELENOO | c.1753C>A p.R585S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV50548509, COSV99955139; called by muse, mutect2, varscan2
- SH2D3A | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99837871; called by muse, mutect2, varscan2
- SLC25A44 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100849285; called by muse, mutect2, varscan2
- SLC30A4 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99970180; called by muse, varscan2
- SLC35G6 | c.37T>G p.S13A | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100262972; called by muse, varscan2
- SLC35G6 | c.79T>C p.W27R | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV100262973; called by muse, varscan2
- SLC39A12 | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101069918; called by muse, mutect2, varscan2
- SNX7 | c.633A>T p.Q211H | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV100068723, COSV60269983; called by muse, mutect2, varscan2
- SPAG17 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100308455; called by muse, mutect2, varscan2
- SPEF2 | c.2376G>A p.M792I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100606752, COSV61551278; called by muse, mutect2, varscan2
- SSTR5 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV99559591; called by muse, mutect2, varscan2
- STAB1 | c.5719G>T p.A1907S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.025); catalogued as COSV100194680; called by muse, mutect2, varscan2
- STAG3 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.304); catalogued as COSV100425756; called by muse, mutect2, varscan2
- STXBP5L | c.2871A>T p.Q957H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56499374, COSV99872886; called by muse, mutect2, varscan2
- SUGCT | c.45C>A p.C15* | Nonsense Mutation (SNP) | VAF 58/260 reads (22%) | catalogued as COSV100000694; called by muse, mutect2, varscan2
- SYCP1 | c.1267A>T p.T423S | Missense Mutation (SNP) | VAF 326/523 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101050830; called by muse, mutect2, varscan2
- TLE1 | c.235-2A>T p.X79_splice | Splice Site (SNP) | VAF 36/66 reads (55%) | catalogued as COSV100915961; called by muse, mutect2, varscan2
- TMEM39A | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.845); catalogued as COSV100052334, COSV59901354; called by muse, mutect2, varscan2
- TRIM67 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV100792070; called by muse, mutect2, varscan2
- TRPM1 | c.3056T>C p.I1019T | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as rs905376764, COSV99855603; called by muse, mutect2, varscan2
- TUT4 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1169281567, COSV99931998; called by muse, mutect2, varscan2
- UNC13B | c.4008+1G>A p.X1336_splice | Splice Site (SNP) | VAF 30/46 reads (65%) | catalogued as rs780641411, COSV101036422; called by muse, mutect2, varscan2
- UNC79 | c.5389C>A p.P1797T (on ENST00000393151 / NM_001346218.2; = p.P1620T on NM_020818.5) | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as COSV99826560; called by muse, mutect2, varscan2
- UPK1A | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99721813; called by muse, mutect2, varscan2
- USP4 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99649143, COSV99649227; called by muse, mutect2, varscan2
- WDR27 | c.1686G>T p.L562F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV100358424; called by muse, mutect2, varscan2
- ZBED1 | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100585363; called by muse, mutect2
- ZNF382 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 186/313 reads (59%) | SIFT tolerated (0.86); PolyPhen benign (0.351); catalogued as COSV53091405, COSV99497597; called by muse, mutect2, varscan2
- ZNF462 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs760725722, COSV52935303, COSV99471886; called by muse, mutect2, varscan2
- ZNF556 | c.1003A>T p.R335* | Nonsense Mutation (SNP) | VAF 66/120 reads (55%) | catalogued as COSV100298637; called by muse, mutect2, varscan2
- ARID1A | c.6683_6706delinsCA p.V2228Afs*32 | Frame Shift Del (DEL) | VAF 26/35 reads (74%) | called by pindel, varscan2*
- CCDC71L | c.123_124del p.Y42Lfs*9 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | called by pindel, varscan2
- CDH19 | c.194del p.Q65Rfs*2 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- EPG5 | c.5345dup p.S1783Vfs*2 | Frame Shift Ins (INS) | VAF 44/169 reads (26%) | called by mutect2, pindel, varscan2
- FLRT2 | c.1385del p.V462Efs*9 | Frame Shift Del (DEL) | VAF 64/140 reads (46%) | called by mutect2, pindel, varscan2
- MAP1S | c.2438_2439del p.T813Rfs*13 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by pindel, varscan2
- PGS1 | c.130_143+5del p.X44_splice | Splice Site (DEL) | VAF 36/60 reads (60%) | called by mutect2, pindel, varscan2
- PI4K2A | c.1407T>G p.F469L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by mutect2, varscan2
- PI4K2A | c.1411_1434del p.S471_W478del | In Frame Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.96877_96896del p.N32293* (on ENST00000591111; = p.N24869* on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.40C>T p.L14= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as rs1463795260, COSV99362278; called by muse, mutect2, varscan2
- AJUBA | c.1314C>T p.G438= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99400884; called by muse, mutect2, varscan2
- ALDH8A1 | c.1107A>G p.A369= | Silent (SNP) | VAF 60/71 reads (85%) | catalogued as COSV99664548; called by muse, mutect2, varscan2
- CCR5 | c.981C>T p.F327= | Silent (SNP) | VAF 69/105 reads (66%) | catalogued as COSV99433241; called by muse, mutect2, varscan2
- CD5L | c.297A>C p.T99= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100941021, COSV63821851; called by muse, mutect2, varscan2
- CREB3L4 | c.60C>T p.F20= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs746004905, COSV99676662; called by muse, mutect2, varscan2
- CSF1 | c.864C>T p.N288= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs1179661516, COSV100294374; called by muse, mutect2, varscan2
- CSMD1 | c.5517G>T p.S1839= (on ENST00000520002; = p.S1838= on NM_033225.6) | Silent (SNP) | VAF 79/126 reads (63%) | catalogued as COSV100145522, COSV100153121; called by muse, mutect2, varscan2
- DDX53 | c.1398C>T p.P466= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV100028769; called by muse, mutect2
- DNAH9 | c.4368G>A p.R1456= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV52355115; called by muse, mutect2, varscan2
- DST | c.1615C>T p.L539= (on ENST00000361203 / NM_001374722.1; = p.L213= on NM_001723.6) | Silent (SNP) | VAF 100/205 reads (49%) | catalogued as rs1169664973, COSV99753075; called by muse, mutect2, varscan2
- EGR4 | c.861C>T p.P287= (on ENST00000545030; = p.P184= on NM_001965.4) | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as rs779921623, COSV71531921; called by muse, mutect2, varscan2
- ENO3 | c.387C>T p.P129= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1284491843, COSV99850555; called by muse, mutect2, varscan2
- FNDC1 | c.720G>T p.R240= | Silent (SNP) | VAF 48/55 reads (87%) | catalogued as COSV99795274; called by muse, mutect2, varscan2
- GPR63 | c.15A>T p.A5= | Silent (SNP) | VAF 71/84 reads (85%) | catalogued as COSV100013216; called by muse, mutect2, varscan2
- HEATR5A | c.2889A>G p.L963= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs767100519, COSV101119761; called by muse, mutect2, varscan2
- INSL3 | c.45T>A p.P15= | Silent (SNP) | VAF 74/141 reads (52%) | catalogued as COSV100427534; called by muse, mutect2, varscan2
- KCNN1 | c.654G>T p.A218= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99715738; called by muse, mutect2, varscan2
- KRT9 | c.657A>T p.T219= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV99879087; called by muse, mutect2, varscan2
- MFSD9 | c.117C>G p.A39= | Silent (SNP) | VAF 90/146 reads (62%) | catalogued as rs1228049483, COSV99301985; called by muse, varscan2
- NEO1 | c.1779T>G p.S593= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99981527; called by muse, mutect2, varscan2
- NTSR2 | c.588G>T p.V196= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100183848; called by muse, mutect2, varscan2
- OR2T2 | c.759C>T p.Y253= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as rs763553843, COSV61618280; called by muse, mutect2, varscan2
- OSBPL2 | c.667C>T p.L223= (on ENST00000313733 / NM_144498.4; = p.L211= on NM_014835.4) | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100569189; called by muse, mutect2, varscan2
- PCDHGA12 | c.150G>A p.R50= | Silent (SNP) | VAF 136/286 reads (48%) | catalogued as rs1054175762, COSV99338897; called by muse, mutect2, varscan2
- POSTN | c.927C>A p.L309= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV101123281, COSV65714218; called by muse, mutect2, varscan2
- PPP1R1B | c.459A>T p.T153= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV99566136; called by muse, mutect2, varscan2
- PPP4R3B | c.840A>G p.P280= | Silent (SNP) | VAF 98/302 reads (32%) | catalogued as COSV99701633; called by muse, mutect2, varscan2
- PRKAR1B | c.555C>T p.Y185= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs756315463, COSV64317938; called by muse, mutect2, varscan2
- RAP2B | c.147G>T p.S49= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV100058863; called by muse, mutect2, varscan2
- SFMBT2 | c.303G>T p.G101= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV100738667; called by muse, mutect2, varscan2
- SLC17A6 | c.1059T>A p.A353= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV99581074; called by muse, mutect2, varscan2
- STT3A | c.366C>T p.L122= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV101205135; called by muse, mutect2, varscan2
- TLR7 | c.246A>T p.P82= | Silent (SNP) | VAF 187/201 reads (93%) | catalogued as COSV101027785; called by muse, mutect2, varscan2
- TRIOBP | c.2649C>T p.P883= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as COSV100730747; called by muse, mutect2, varscan2
- TSPYL2 | c.432G>A p.G144= | Silent (SNP) | VAF 11/185 reads (6%) | catalogued as rs376774006, COSV100212119; called by muse, mutect2
- AC092718.9 | chr16:81151796 C>T | 5'Flank (SNP) | VAF 80/166 reads (48%) | catalogued as rs1406397133; called by muse, mutect2, varscan2
- HERC2P3 | n.1768G>A | RNA (SNP) | VAF 79/152 reads (52%) | catalogued as rs528396027; called by muse, mutect2, varscan2
- IMP3 | c.*2G>A | 3'UTR (SNP) | VAF 15/76 reads (20%) | catalogued as rs1350403049, COSV100145754; called by muse, mutect2, varscan2
- NBPF7 | n.389G>C | RNA (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- RPL23A | c.26-101C>A | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99411685; called by muse, mutect2, varscan2
